Gene-level copy-number profile of tumor specimen TCGA-C5-A7X5-01A from TCGA case TCGA-C5-A7X5, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, keratinizing, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IVB; Tumor grade: G3; Age at diagnosis: 72.7 years (26,542 days).
Specimen TCGA-C5-A7X5-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-CESC.f50365c4-feff-46fd-8c93-c4359c580c91.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-C5-A7X5-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 806 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/2cb672a7-cf20-4198-be28-77e3959d9570

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 1,353; copy number 2: 12,711; copy number 3: 25,954; copy number 4: 13,534; copy number 5: 2,892; copy number 6: 1,593; copy number 7: 940; copy number 8: 459; copy number 9: 122; copy number 10: 53; copy number 11: 135; copy number 12: 70; copy number 21: 1.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-C5-A7X5-01A-11D-A36I-01): tumor purity 0.84, ploidy 3.22, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,780 genes in 20 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:48,532,854–50,023,954, 1 gene, copy number 9 (within-gene range 2–9): AGBL4.
- chr1:49,025,595–50,203,772, 10 genes, copy number 9 (within-gene range 2–9): AC099788.1, AGBL4-AS1, AGBL4-IT1, AL390023.1, ZNF859P, AL645730.1, MTND2P29, ELAVL4, AL583843.1, ELAVL4-AS1.
- chr1:53,304,536–53,368,245, 5 genes, copy number 8: AL355483.2, LINC01771, AC119428.2, AC119428.1, LINC02812.
- chr1:55,329,288–56,070,513, 9 genes, copy number 8 (within-gene range 2–8): AL603840.1, GOT2P1, MTCO2P34, RN7SKP291, RNU6-830P, Y_RNA, LINC01755, LINC01753, PIGQP1.
- chr1:56,718,789–63,361,179, 90 genes, copy number 7–12 (broad region; genes not listed).
- chr1:70,144,805–70,253,052, 4 genes, copy number 11: LRRC40, RN7SL242P, SRSF11, AL353771.1.
- chr2:20,175,346–20,246,387, 5 genes, copy number 9: RN7SL140P, RNU6-961P, SDC1, DRG1P1, RNU7-113P.
- chr2:110,122,311–114,007,304, 126 genes, copy number 7–21 (broad region; genes not listed).
- chr3:172,425,850–198,222,513, 522 genes, copy number 7–12 (broad region; genes not listed).
- chr7:86,216,785–86,864,884, 4 genes, copy number 9–12: SOCS5P1, GRM3, AC005009.1, GRM3-AS1.
- chr7:88,420,167–88,756,725, 7 genes, copy number 7 (within-gene range 3–7): AC002069.2, EIF4A1P13, AC002069.1, AC002069.4, AC002069.3, KPNA2P2, PQLC1P1.
- chr7:89,754,620–91,556,848, 25 genes, copy number 8 (within-gene range 2–8): RNU6-274P, STEAP2-AS1, AC004969.1, DPY19L2P4, STEAP1, STEAP2, CFAP69, Y_RNA, AC002064.2, AC002064.1, FAM237B, GTPBP10, AC002064.3, CLDN12, AC006153.1, CDK14, AC002456.2, AC002456.1, TVP23CP1, AC002458.1, PTP4A1P3, FZD1, AC079760.2, NIPA2P1, AC079760.1.
- chr7:98,794,718–100,968,347, 123 genes, copy number 7 (within-gene range 2–7) (broad region; genes not listed).
- chr12:37,575,587–39,443,390, 21 genes, copy number 7 (within-gene range 5–7): ZNF970P, AK6P2, CLUHP8, AC079460.1, AC079460.2, RNA5SP358, RNA5SP359, TUBB8P5, AC117372.1, NF1P12, Y_RNA, ALG10B, AC087897.1, AC087897.2, CPNE8, CPNE8-AS1, AC018448.2, AC018448.1, LINC02406, AC084373.1, KIF21A.
- chr12:40,978,744–42,717,120, 31 genes, copy number 7: AC015540.1, PDZRN4, AC090531.1, RNA5SP360, MTND2P17, MTND1P24, LINC02400, AC090630.1, AC006197.1, AC006197.2, AC023513.1, GXYLT1, YAF2, PPHLN1, AC020629.1, ZCRB1, MIR7851, SNORA74, AC079684.1, RNU6-249P, AC079601.2, Y_RNA, PRICKLE1, AC079601.1, AC079600.3, LINC02402, AC079600.2, AC079600.1, LINC02451, RPS27P21, LINC02450.
- chr12:58,920,639–74,664,141, 268 genes, copy number 7–11 (within-gene range 5–11) (broad region; genes not listed).
- chr18:63,389,190–63,505,085, 5 genes, copy number 7: VPS4B, AC036176.2, SERPINB5, AC036176.3, ATP5MC1P6.
- chr19:18,058,995–20,571,095, 135 genes, copy number 7–8 (within-gene range 5–8) (broad region; genes not listed).
- chr19:35,399,511–40,285,536, 263 genes, copy number 8–11 (broad region; genes not listed).
- chr20:32,631,625–36,030,700, 126 genes, copy number 7–8 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1,353. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
